Somatic mutation profile of tumor specimen TCGA-05-4403-01A (aliquot TCGA-05-4403-01A-01D-1265-08) from TCGA case TCGA-05-4403, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 76.3 years (27,881 days).
Specimen TCGA-05-4403-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38b27442-bdfb-488f-8ad1-ef837020aeff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-4403-10A (Blood Derived Normal), aliquot TCGA-05-4403-10A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ff327bf-3a69-4255-9504-10d14725eeb4

The open-access MAF lists 144 somatic variants for this specimen: 111 protein-altering or splice-affecting, 31 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 31, Nonsense Mutation 10, Frame Shift Del 3, In Frame Del 2, Frame Shift Ins 2, Intron 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANGPT2 | c.677T>A p.I226N | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV57341149; called by muse, mutect2, varscan2
- ANKFN1 | c.1918G>C p.V640L | Missense Mutation (SNP) | VAF 48/241 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as COSV100593921, COSV59453373, COSV59462313; called by muse, mutect2, varscan2
- ATP8A2 | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.385); catalogued as COSV54979965; called by muse, mutect2, varscan2
- AUTS2 | c.2701C>T p.R901C | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.878); catalogued as rs976081207, COSV100719314, COSV61418157; called by muse, mutect2, varscan2
- C2orf76 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.618); catalogued as rs780592227, COSV58347061; called by muse, mutect2, varscan2
- CCDC148 | c.428A>G p.H143R | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV51772556; called by muse, mutect2, varscan2
- CCDC85A | c.676A>T p.K226* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as COSV68156268; called by muse, mutect2, varscan2
- CCDC91 | c.445G>T p.E149* | Nonsense Mutation (SNP) | VAF 8/16 reads (50%) | catalogued as COSV60350287; called by muse, mutect2
- CCNF | c.17-2A>T p.X6_splice | Splice Site (SNP) | VAF 52/246 reads (21%) | catalogued as rs111704404, COSV53543948; called by muse, mutect2, varscan2
- CHRNA6 | c.313A>C p.I105L | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as COSV52378464, COSV99373020; called by muse, mutect2, varscan2
- CNTN1 | c.2107G>T p.G703C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61646693; called by muse, mutect2
- CNTN5 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.871); catalogued as COSV54367546; called by muse, mutect2, varscan2
- DPP10 | c.1998G>C p.K666N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV59740935; called by muse, varscan2
- DSC1 | c.1720G>T p.A574S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV57145486, COSV57152642; called by muse, mutect2, varscan2
- DTX3 | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 113/528 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.129); catalogued as COSV54091367; called by muse, mutect2, varscan2
- EHBP1L1 | c.3268G>A p.D1090N | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.066); catalogued as rs1286898955, COSV58575593; called by muse, mutect2, varscan2
- ENPP3 | c.1214G>T p.R405L | Missense Mutation (SNP) | VAF 52/227 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62957421; called by muse, mutect2, varscan2
- EPHX3 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as rs1226054291, COSV55655559; called by muse, mutect2, varscan2
- FAM124B | c.438T>A p.F146L | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV54740334; called by muse, mutect2, varscan2
- FAM47B | c.554G>C p.G185A | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.121); catalogued as COSV61457250; called by muse, mutect2, varscan2
- FLG | c.7380C>A p.D2460E | Missense Mutation (SNP) | VAF 120/660 reads (18%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV64251801; called by muse, varscan2
- FLG | c.6038C>G p.S2013* | Nonsense Mutation (SNP) | VAF 196/983 reads (20%) | catalogued as COSV64240758, COSV64251809; called by muse, mutect2, varscan2
- FLT1 | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56746227; called by muse, mutect2, varscan2
- GABRA6 | c.1205T>C p.V402A | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV50899199; called by muse, mutect2, varscan2
- GABRR1 | c.379T>C p.Y127H | Missense Mutation (SNP) | VAF 93/421 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65621044; called by muse, mutect2, varscan2
- GCLC | c.535G>T p.D179Y (on ENST00000643939; = p.D177Y on NM_001498.4) | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57598357; called by muse, mutect2, varscan2
- GET4 | c.662A>T p.Q221L | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV56257259; called by muse, mutect2, varscan2
- GLUD1 | c.1240G>C p.D414H | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.422); catalogued as COSV53281794; called by muse, mutect2, varscan2
- GMPR | c.407A>T p.E136V | Missense Mutation (SNP) | VAF 51/243 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV52475891; called by muse, mutect2, varscan2
- HTR1E | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs776555108, COSV59506888; called by muse, mutect2, varscan2
- IFT52 | c.1087G>T p.E363* | Nonsense Mutation (SNP) | VAF 24/94 reads (26%) | catalogued as COSV65976460; called by muse, mutect2, varscan2
- ITGA11 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs572157984, COSV100241481, COSV59882854; called by muse, mutect2, varscan2
- ITGAL | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs145951975; called by muse, mutect2, varscan2
- KIF4B | c.2701A>T p.M901L | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs765883151, COSV70531972; called by muse, mutect2, varscan2
- KMT2D | c.5140C>T p.P1714S | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV56494634; called by muse, mutect2, varscan2
- KRTAP24-1 | c.163C>A p.L55I | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.441); catalogued as COSV61089673; called by muse, mutect2, varscan2
- LCP1 | c.1181C>A p.T394K | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745890489, COSV59943906; called by muse, mutect2, varscan2
- LRRIQ3 | c.458C>A p.A153E | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs752476802, COSV100598437; called by muse, mutect2
- MARK3 | c.797T>G p.L266* | Nonsense Mutation (SNP) | VAF 31/77 reads (40%) | catalogued as COSV53517532; called by muse, mutect2, varscan2
- MCCC2 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.094); catalogued as rs553444289, COSV60157435; called by muse, mutect2, varscan2
- MCF2 | c.1563T>G p.Y521* | Nonsense Mutation (SNP) | VAF 20/39 reads (51%) | catalogued as COSV58496672; called by muse, mutect2, varscan2
- MED1 | c.3991G>T p.V1331L | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs762005333, COSV56129262; called by muse, mutect2, varscan2
- MET | c.1426C>T p.H476Y | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV59261902; called by muse, mutect2, varscan2
- MICAL2 | c.3329C>T p.P1110L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); catalogued as rs1354406267, COSV56325034; called by muse, mutect2, varscan2
- MUC16 | c.35699C>T p.S11900F | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.02); catalogued as COSV67501597; called by muse, mutect2, varscan2
- MUC16 | c.3607C>G p.P1203A | Missense Mutation (SNP) | VAF 84/324 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.329); catalogued as rs573135410, COSV67501607; called by muse, varscan2
- MYH7 | c.3004G>A p.A1002T | Missense Mutation (SNP) | VAF 71/256 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as COSV62525054; called by muse, mutect2, varscan2
- MYO18B | c.7601C>T p.A2534V | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs532589500, COSV59124764; called by muse, mutect2, varscan2
- NCAPD3 | c.1868G>T p.G623V | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748639067, COSV73259058; called by muse, mutect2, varscan2
- NEDD8 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.328); catalogued as COSV51660913; called by muse, mutect2, varscan2
- NLRP12 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.989); catalogued as COSV60757068; called by muse, mutect2, varscan2
- NLRP3 | c.1241G>C p.W414S | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV60232401; called by muse, mutect2, varscan2
- NOTCH2 | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56709415; called by muse, mutect2, varscan2
- NVL | c.2333C>T p.A778V | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV55877053; called by muse, mutect2, varscan2
- OSBPL2 | c.1036G>A p.D346N (on ENST00000313733 / NM_144498.4; = p.D334N on NM_014835.4) | Missense Mutation (SNP) | VAF 43/214 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs754323214, COSV58218189; called by muse, mutect2, varscan2
- OTX2 | c.413C>A p.S138* (on ENST00000408990 / NM_172337.3; = p.S146* on NM_021728.4) | Nonsense Mutation (SNP) | VAF 29/82 reads (35%) | catalogued as CM098183, COSV59767990; called by muse, mutect2, varscan2
- P2RY1 | c.140C>T p.T47M | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV59310684; called by muse, mutect2, varscan2
- PACS2 | c.2578G>T p.D860Y | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57658121; called by muse, mutect2, varscan2
- PDCD11 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.13); catalogued as COSV63935734; called by muse, mutect2, varscan2
- PIP | c.370C>A p.P124T | Missense Mutation (SNP) | VAF 64/318 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as COSV52121908; called by muse, mutect2, varscan2
- POLB | c.80A>G p.K27R | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV99612437; called by muse, mutect2, varscan2
- PPME1 | c.827A>G p.D276G | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV60298825; called by muse, mutect2, varscan2
- PPP3R2 | c.381G>A p.W127* | Nonsense Mutation (SNP) | VAF 34/131 reads (26%) | catalogued as rs1202597957, COSV100701349; called by muse, mutect2, varscan2
- PREPL | c.1027A>G p.M343V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs771442588, COSV53219890; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRH1 | c.412C>T p.H138Y | Missense Mutation (SNP) | VAF 99/367 reads (27%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.06); catalogued as rs372138349; called by muse, mutect2, varscan2
- PRMT2 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.259); catalogued as COSV99388430; called by muse, mutect2, varscan2
- PTBP2 | c.1544A>C p.Q515P (on ENST00000426398 / NM_001300986.2; = p.Q506P on NM_021190.4) | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.177); catalogued as COSV100930144, COSV64626866; called by muse, mutect2, varscan2
- RANBP6 | c.2237G>A p.G746D | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs202193240, COSV99423923; called by muse, mutect2, varscan2
- RAPGEF2 | c.1807C>G p.P603A | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV52434835; called by muse, mutect2, varscan2
- RBM10 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | catalogued as COSV61312952; called by muse, mutect2, varscan2
- ROBO2 | c.3373G>T p.D1125Y | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV59899737; called by muse, mutect2, varscan2
- RSF1 | c.2252A>T p.K751I | Missense Mutation (SNP) | VAF 69/280 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV57847077; called by muse, mutect2, varscan2
- RTL9 | c.112G>C p.D38H | Missense Mutation (SNP) | VAF 76/182 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.667); catalogued as COSV101511615, COSV71826048; called by muse, mutect2, varscan2
- RTL9 | c.2221G>T p.A741S | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101511616, COSV101511827; called by muse, mutect2, varscan2
- RYBP | c.54C>G p.S18R | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV72180417, COSV72180926, COSV72181231; called by muse, mutect2, varscan2
- RYR1 | c.6419G>T p.R2140L | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as COSV62093789, COSV62113663; called by muse, mutect2, varscan2
- SCG3 | c.917T>A p.L306Q | Missense Mutation (SNP) | VAF 41/258 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55023649; called by muse, mutect2, varscan2
- SEC23A | c.1490C>T p.T497I | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV56979874; called by muse, mutect2, varscan2
- SETD6 | c.344C>T p.A115V (on ENST00000219315 / NM_001160305.4; = p.A91V on NM_024860.3) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as COSV99261645; called by muse, mutect2
- SH2B1 | c.361G>T p.G121C | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV59468057; called by muse, mutect2, varscan2
- SLC17A6 | c.319G>T p.G107W | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54139110; called by muse, mutect2, varscan2
- SLC34A2 | c.1205C>A p.T402N | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV65943425; called by muse, mutect2, varscan2
- SLC35F1 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV64511391; called by muse, mutect2, varscan2
- SLC4A5 | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752681525, COSV61031785; called by muse, mutect2, varscan2
- SP140L | c.1585G>T p.V529L | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV99706668; called by mutect2, varscan2
- SPTY2D1 | c.325C>T p.Q109* | Nonsense Mutation (SNP) | VAF 41/196 reads (21%) | catalogued as COSV60475906; called by muse, mutect2, varscan2
- TLL1 | c.2269C>T p.R757C | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs376797148; called by muse, mutect2, varscan2
- TMEM132D | c.2003T>A p.L668H | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67163109; called by muse, mutect2, varscan2
- TNKS1BP1 | c.542G>T p.R181L | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV64103043; called by muse, mutect2, varscan2
- TOPBP1 | c.1772C>T p.A591V | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.362); catalogued as rs774702840, COSV53443193; called by muse, mutect2, varscan2
- TOX2 | c.44G>T p.R15L | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.022); catalogued as rs575271004, COSV57897631; called by muse, mutect2, varscan2
- TRANK1 | c.2085G>T p.L695F | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV57166925; called by muse, mutect2, varscan2
- TRMT12 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.377); catalogued as COSV60777878; called by muse, mutect2, varscan2
- TRPM3 | c.2545G>A p.D849N (on ENST00000357533 / NM_001366142.2; = p.D692N on NM_020952.6) | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs755973554, COSV62596762; called by muse, mutect2, varscan2
- TTI2 | c.1090A>G p.R364G | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as rs752283630, COSV62453898; called by muse, mutect2, varscan2
- UBE2L6 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 80/338 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.058); catalogued as rs868642148, COSV54702734; called by muse, mutect2, varscan2
- USP6 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as rs1197561613, COSV100002912; called by muse, mutect2, varscan2
- UTP23 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs778049882, COSV100561077; called by muse, mutect2, varscan2
- UTY | c.1403G>C p.R468P | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100229326; called by muse, mutect2, varscan2
- ZNF213 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV67728377; called by muse, mutect2, varscan2
- ZNF875 | c.1673G>T p.C558F | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100183015, COSV60992304; called by muse, mutect2, varscan2
- ZSCAN4 | c.1062C>A p.D354E | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.168); catalogued as COSV56595551; called by muse, mutect2, varscan2
- DHODH | c.441_443del p.F148del | In Frame Del (DEL) | VAF 20/87 reads (23%) | called by mutect2, pindel, varscan2
- HS3ST5 | c.387_389del p.D129del | In Frame Del (DEL) | VAF 28/224 reads (13%) | called by pindel, varscan2
- HSDL1 | c.109dup p.S37Kfs*7 | Frame Shift Ins (INS) | VAF 31/154 reads (20%) | called by mutect2, pindel, varscan2
- IGKV1-9 | c.8T>G p.M3R | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- IGKV1-9 | c.7A>C p.M3L | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RIMBP2 | c.2204del p.P735Rfs*55 | Frame Shift Del (DEL) | VAF 21/98 reads (21%) | called by mutect2, pindel, varscan2
- SYNE1 | c.20285del p.C6762Sfs*4 (on ENST00000367255 / NM_182961.4; = p.C6691Sfs*4 on NM_033071.3) | Frame Shift Del (DEL) | VAF 31/143 reads (22%) | called by mutect2, pindel, varscan2
- TAAR5 | c.675dup p.A226Cfs*22 | Frame Shift Ins (INS) | VAF 14/100 reads (14%) | called by mutect2, pindel, varscan2
- ZNF831 | c.751del p.H251Tfs*11 | Frame Shift Del (DEL) | VAF 29/127 reads (23%) | called by mutect2, pindel, varscan2
- BBOX1 | c.1045C>A p.R349= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as rs200897398, COSV54194993; called by muse, mutect2, varscan2
- BRSK1 | c.945G>A p.L315= | Silent (SNP) | VAF 34/133 reads (26%) | catalogued as COSV58667667; called by muse, mutect2, varscan2
- C1QTNF7 | c.735C>A p.V245= | Silent (SNP) | VAF 64/178 reads (36%) | catalogued as COSV54857203; called by muse, mutect2, varscan2
- CFAP47 | c.1284A>G p.E428= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV99934246; called by muse, mutect2, varscan2
- ESRRG | c.738G>A p.P246= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs762615151, COSV63185102; called by muse, mutect2, varscan2
- FAM83B | c.153A>T p.R51= | Silent (SNP) | VAF 23/116 reads (20%) | catalogued as COSV60927969; called by muse, mutect2, varscan2
- GYS1 | c.1836G>A p.A612= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs769733892, COSV54401971; called by muse, mutect2, varscan2
- KCNN1 | c.954G>A p.L318= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV55842858; called by muse, mutect2, varscan2
- LRTM1 | c.267G>T p.L89= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV55561851, COSV99835882; called by muse, mutect2, varscan2
- MEIOC | c.1758T>C p.N586= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV100740136, COSV63439787; called by muse, mutect2, varscan2
- MMP11 | c.414C>T p.S138= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as rs199514530, COSV53157896, COSV53158357; called by muse, mutect2, varscan2
- MST1R | c.3900G>A p.L1300= | Silent (SNP) | VAF 29/107 reads (27%) | catalogued as COSV56575169; called by muse, mutect2, varscan2
- MTR | c.2967G>C p.P989= | Silent (SNP) | VAF 21/127 reads (17%) | catalogued as COSV63966339, COSV63966600; called by muse, mutect2, varscan2
- NDST3 | c.1278C>T p.G426= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as rs767900257, COSV56619667; called by muse, mutect2, varscan2
- NECTIN1 | c.747A>G p.V249= | Silent (SNP) | VAF 19/122 reads (16%) | catalogued as COSV50610662; called by muse, mutect2, varscan2
- PCDH17 | c.933T>C p.Y311= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV64980596; called by muse, mutect2, varscan2
- PDP2 | c.1110C>G p.T370= | Silent (SNP) | VAF 36/148 reads (24%) | catalogued as COSV100305811, COSV61240027; called by muse, mutect2, varscan2
- PSKH2 | c.720C>T p.T240= | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as COSV52613169, COSV99405210; called by muse, mutect2, varscan2
- PTPN23 | c.1992C>T p.A664= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs752849441, COSV55549260; called by muse, mutect2, varscan2
- RAB36 | c.513C>T p.P171= | Silent (SNP) | VAF 47/230 reads (20%) | catalogued as COSV54075843; called by muse, mutect2, varscan2
- RAB6D | c.753C>A p.V251= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as COSV72151711; called by muse, mutect2, varscan2
- RFX3 | c.1728G>T p.V576= | Silent (SNP) | VAF 56/144 reads (39%) | catalogued as COSV56526718; called by muse, mutect2, varscan2
- SELENOM | c.327G>C p.V109= | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as COSV100293895, COSV60781751; called by muse, mutect2, varscan2
- SGCZ | c.852C>T p.C284= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as rs1456069136, COSV66020848; called by muse, mutect2, varscan2
- SNX13 | c.1089A>T p.A363= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV68068831; called by muse, mutect2, varscan2
- SRSF2 | c.240G>C p.L80= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV100333428, COSV100333592; called by muse, mutect2, varscan2
- TMEM168 | c.513T>C p.T171= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV57182954; called by muse, mutect2, varscan2
- UBE4B | c.2634A>T p.A878= (on ENST00000343090 / NM_001105562.3; = p.A749= on NM_006048.5) | Silent (SNP) | VAF 49/248 reads (20%) | catalogued as COSV53543993; called by muse, mutect2, varscan2
- VCAM1 | c.1413C>A p.I471= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as COSV54121061, COSV54122876; called by muse, mutect2, varscan2
- ZCCHC14 | c.1902T>C p.R634= (on ENST00000268616; = p.R771= on NM_015144.3) | Silent (SNP) | VAF 31/209 reads (15%) | catalogued as COSV51891136; called by muse, mutect2, varscan2
- ZMYND15 | c.1869G>A p.T623= (on ENST00000433935 / NM_001136046.3; = p.T584= on NM_032265.2) | Silent (SNP) | VAF 30/169 reads (18%) | catalogued as rs988749271, COSV99350904; called by muse, mutect2, varscan2
- DCHS2 | n.3320C>A | RNA (SNP) | VAF 15/269 reads (6%) | catalogued as COSV59741630; called by muse, mutect2
- RPS3A | c.355-768T>C | Intron (SNP) | VAF 16/71 reads (23%) | catalogued as COSV99923594; called by muse, mutect2, varscan2
